Gene-level copy-number profile of tumor specimen TCGA-VS-A9UH-01A from TCGA case TCGA-VS-A9UH, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 53.3 years (19,454 days).
Specimen TCGA-VS-A9UH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.e3a38918-2504-4c0e-82a0-09c50a83e009.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VS-A9UH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 389 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/378b071a-6fdc-4431-8809-841895ab43ab

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 6,410; copy number 1: 24,199; copy number 2: 24,584; copy number 3: 2,555; copy number 4: 1,549; copy number 5: 433; copy number 6: 38; copy number 7: 108; copy number 8: 327; copy number 11: 1; copy number 13: 29; copy number 21: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VS-A9UH-01A-11D-A42N-01): tumor purity 0.23, ploidy 3.56, whole-genome doublings 1.

Caution: 5,890 autosomal genes are at 0 copies in this file, far more than a typical tumor; the lists below are given as recorded.

Homozygous deletions (total copy number 0; autosomes only): 5,890 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–111,846,447, 1,610 genes (within-gene range 0–8) (broad region; genes not listed).
- chr6:30,516,266–30,557,174, 2 genes: LINC02569, GNL1.
- chr7:142,399,860–142,400,377, 1 gene: TRBV10-1.
- chr10:44,712–93,806,272, 1,609 genes (broad region; genes not listed).
- chr10:93,993,931–133,642,894, 702 genes (within-gene range 0–2) (broad region; genes not listed).
- chr11:55,935,456–56,038,191, 8 genes: OR5I1, OR10AF1P, OR10AK1P, OR10AG1, OR7E5P, OR5F1, OR5F2P, OR5AS1.
- chr13:29,339,566–29,339,869, 1 gene: AL596092.1.
- chr13:70,564,267–70,564,437, 1 gene: AL445264.1.
- chr15:26,543,546–26,939,539, 1 gene (within-gene range 0–8): GABRB3.
- chr15:26,657,030–101,933,350, 1,914 genes (broad region; genes not listed).
- chr17:82,359,247–83,095,122, 37 genes: TEX19, AC132938.4, UTS2R, AC132938.1, OGFOD3, AC132938.2, Y_RNA, HEXD, HEXD-IT1, CYBC1, AC132938.6, AC132938.3, NARF, AC132938.5, NARF-AS1, NARF-IT1, FOXK2, AC124283.4, AC124283.3, AC124283.2, AC124283.1, WDR45B, AC124283.5, RAB40B, MIR4525, AC024361.2, FN3KRP, AC024361.3, FN3K, AC024361.1, TBCD, AC068014.1, ZNF750, AC087222.1, B3GNTL1, AC130371.1, METRNL.
- chr20:14,884,250–15,022,958, 4 genes: MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 5,040 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:111,732,497–198,222,513, 1,575 genes, copy number 3–4 (within-gene range 0–8) (broad region; genes not listed).
- chr5:58,198–25,190,956, 404 genes, copy number 4–5 (broad region; genes not listed).
- chr5:25,188,059–25,188,778, 1 gene, copy number 5: AC099499.2.
- chr5:79,774,348–79,849,846, 3 genes, copy number 3 (within-gene range 1–3): AC008496.2, AC008496.3, AC008496.1.
- chr6:30,286,690–30,494,194, 13 genes, copy number 6 (within-gene range 1–6): HCG18, TRIM39, TRIM39-RPP21, RPP21, HLA-N, AL662795.1, UBQLN1P1, MICC, AL662873.1, TMPOP1, SUCLA2P1, RANP1, HLA-E.
- chr6:30,557,280–32,589,848, 191 genes, copy number 8 (broad region; genes not listed).
- chr9:60,914,407–93,858,340, 546 genes, copy number 3–21 (within-gene range 2–21) (broad region; genes not listed).
- chr9:93,951,627–104,695,485, 220 genes, copy number 3–7 (within-gene range 3–14) (broad region; genes not listed).
- chr12:66,767–34,249,958, 850 genes, copy number 3–4 (broad region; genes not listed).
- chr14:71,181,456–71,182,106, 1 gene, copy number 7: AC004817.2.
- chr14:105,836,765–106,875,071, 183 genes, copy number 3–7 (broad region; genes not listed).
- chr15:19,878,555–26,477,840, 299 genes, copy number 3–8 (broad region; genes not listed).
- chr15:26,557,598–26,557,937, 1 gene, copy number 8: AC009878.1.
- chr18:47,390–15,330,282, 376 genes, copy number 3 (broad region; genes not listed).
- chr20:48,821,688–64,313,132, 377 genes, copy number 3 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 24,199. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
